Gene-level copy-number profile of tumor specimen C3L-06089-54 from CPTAC case C3L-06089, project CPTAC-3 (Hematopoietic and reticuloendothelial systems — Myeloid Leukemias). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Hematopoietic system, NOS; Age at diagnosis: 64.1 years (23,404 days).
Specimen C3L-06089-54: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Whole Blood; Biospecimen anatomic site: Blood; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 9277e607-fe41-47e7-b3b3-75c141e0b542.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-06089-50 (buccal cell normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,706 have no estimate.
https://portal.gdc.cancer.gov/files/874ef25c-503f-4d39-bc85-d4a45eba52d9

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 2,856; copy number 2: 56,061.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
